Somatic mutation profile of tumor specimen TCGA-HI-7169-01A (aliquot TCGA-HI-7169-01A-11D-2114-08) from TCGA case TCGA-HI-7169, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.1 years (20,133 days).
Specimen TCGA-HI-7169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d9e3196-4c54-4728-8539-4389ae4bed8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HI-7169-10A (Blood Derived Normal), aliquot TCGA-HI-7169-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03df9e9f-d258-4ee5-94fa-c0461fb84d7f

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 14, Silent 12, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO7 | c.992C>T p.P331L (on ENST00000274979; = p.P277L on NM_001370694.2) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51478389; called by muse, mutect2, varscan2
- CTNNBL1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV63746975; called by muse, mutect2, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- ESAM | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs764844339, COSV54036038; called by muse, mutect2, varscan2
- FAT3 | c.5599G>A p.V1867I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs201824046; called by muse, mutect2, varscan2
- H3C3 | c.55A>C p.K19Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV63551469; called by muse, mutect2, varscan2
- LBR | c.1840A>G p.I614V | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as COSV55291342; called by muse, mutect2
- NKIRAS1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.26); catalogued as COSV60669489; called by muse, mutect2, varscan2
- OR5A2 | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV57391783; called by muse, mutect2, varscan2
- PLCB4 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53815253; called by muse, mutect2, varscan2
- RYR3 | c.11774A>G p.D3925G (on ENST00000389232; = p.D3926G on NM_001036.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV66806085; called by muse, mutect2, varscan2
- SNX17 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773179800, COSV52010081; called by muse, mutect2, varscan2
- TTN | c.94451T>C p.V31484A (on ENST00000591111; = p.V24060A on NM_003319.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | PolyPhen benign (0.27); catalogued as rs771770606, COSV60298859; called by muse, mutect2, varscan2
- RDM1 | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- TMEM131 | c.4703del p.P1568Qfs*26 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- ANK2 | c.2430C>T p.V810= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs766919590, COSV52144691; ClinVar: likely benign; called by muse, mutect2
- ARHGAP31 | c.3138A>C p.L1046= | Silent (SNP) | VAF 43/170 reads (25%) | catalogued as COSV51798042; called by muse, mutect2, varscan2
- CDK2 | c.846T>C p.A282= | Silent (SNP) | VAF 44/196 reads (22%) | catalogued as COSV57187366; called by muse, mutect2, varscan2
- FCSK | c.1383A>G p.E461= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55374814; called by muse, mutect2, varscan2
- HNF4G | c.309C>T p.S103= (on ENST00000354370 / NM_001330561.2; = p.S150= on NM_004133.5) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs1382367333, COSV62972871; called by muse, mutect2, varscan2
- MON2 | c.915A>G p.P305= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as rs369425233; called by muse, mutect2, varscan2
- PCDHGB1 | c.123C>T p.N41= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53902666; called by muse, mutect2, varscan2
- PGAM4 | c.120C>T p.R40= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV58443546; called by muse, mutect2
- RICTOR | c.4755A>C p.S1585= | Silent (SNP) | VAF 47/222 reads (21%) | catalogued as COSV57129372; called by muse, mutect2, varscan2
- TNFRSF13B | c.750C>T p.T250= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV55426002; called by muse, mutect2
- TSPAN15 | c.609C>T p.I203= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as rs1404613093, COSV64782822; called by muse, mutect2, varscan2
- VPS13A | c.9471C>A p.A3157= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV64335689; called by muse, mutect2
